Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JH-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell
NOS 8070/3
Site: Larynx NOS C32.9
J 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

1- "Right SCF skin biopsy"

- . Exudative inflammatory process
- . Absence of neoplasia

2- "Total pharyngolaryngectomy + bilateral wide field resection + bilateral recurrential resection":

- . Well-differentiated squamous cell carcinoma, measuring 6.0 cm, occupying supraglottis, glottis and subglottis, crossing the midline.
- . Presence of bilateral vocal folds infiltration
- . Presence of arytenoid and thyroid cartilages infiltration.
- . Vascular and perineural invasion not detected
- . Epiglottis and pre-glottic fat uninvolved by neoplasia
- . Thyroid uninvolved by neoplasia
- . Surgical margins uninvolved by neoplasia
- . Twenty-four lymph nodes uninvolved by neoplasia (0/24)

Source: NCI Genomic Data Commons file 72308bc8-6756-43c2-b718-80490f75352e (TCGA-UF-A7JH.2785950A-7654-4C51-9F45-F2E6F8D5DC8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).